Surgical pathology report (de-identified scan), TCGA case TCGA-14-1456, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1456-01B (Primary Tumor).

[page 1 of 2]
* Final Report *

AP REPORT

Patient: [REDACTED]

Accession Number: [REDACTED]

Patient Number: [REDACTED]

Date Collected:

Financial Number: [REDACTED]

Date Received:

Room/Bed: [REDACTED]

PT. [REDACTED]

Admitting Physician: [REDACTED]

Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT FRONTAL, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT FRONTAL, EXCISION:
- GLIOBLASTOMA MULTIFORME.
- SEE COMMENT.

TCGA-14-1456

COMMENT:

This infiltrating astrocytoma discloses focal anaplasia, high cellularity, necrosis and microvascular proliferation. These features are indicative of glioblastoma multiforme. However, other areas in this tumor appear to represent lower grade infiltrating astrocytoma. The infiltrative nature of this tumor is confirmed in a neurofilament immunohistochemical stain. A MIB1 proliferation rate is estimated at approximately 10-15% in the higher grade areas of the tumor.

SPECIMEN:

1. Left frontal brain lesion.
2. Left frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Craniotomy, brain tumor. Brain tumor. Left frontal craniotomy.

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation, labeled with

[page 2 of 2]
the patient's name, medical record number and as "left frontal brain lesion." The specimen consists of multiple pieces of tan-red tissue measuring in aggregate 0.7 x 0.7 x 0.3 cm. A representative section is submitted for frozen tissue diagnosis, and the contents of the cryoblock are resubmitted in cassette "FS1A." The remainder of the specimen is submitted in cassette "1B." Immunohistochemical stains MIB1 and neurofilament are ordered on cassette "1B."

Specimen #2 is received in formalin, labeled with the patient's name, medical record number and as "left frontal brain lesion." The specimen consists of numerous fragments of tan-red tissue measuring in aggregate 2.5 x 2.5 x 0.4 cm. Representative sections are submitted in cassettes "2A" and "2B." Approximately 75% of the tissue have been submitted.

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT FRONTAL BRAIN LESION (FROZEN SECTION):
ASTROCYTOMA; GRADING
DEFERRED.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Page 1 (Continued...)

Patient:

Accession Number:

Patient Number:

SPECIAL STAINS:

KI-67	DONE
KI-67	DONE
NF	DONE
NF	DONE

Source: NCI Genomic Data Commons file 48087861-8988-45d2-8556-8fb65a3151b6 (TCGA-14-1456.FD1151FA-9611-4D50-A918-07F3E587879B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).